Surgical pathology report (de-identified scan), TCGA case TCGA-36-1578, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1578-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

DOB/Gender:

Ordering Physician:

F

Final Diagnosis:

A. Right fallopian tube and ovary showing:

- 1) Invasive serous adenocarcinoma involving predominantly the tube (with maximum dimension of 3.5 cm) and ovary (with maximum dimension of 3 cm)- please see comment.
- 2) FIGO tumor grade 3/3 (nuclear score 3; mitotic score 2; architecture score 3).
- 2) The ovarian portion of the tumor is predominantly surface involvement.
- 4) No vascular invasion seen.

B. Specimen labelled "omentum" showing multiple foci of metastatic serous adenocarcinoma; the largest one is 10 cm.

C. Peritoneal washing showing malignant cells consistent with serous carcinoma.

D. TNM: pT3c, Nx, Mx; FIGO stage IIIC.

Final Diagnosis Comment:

The fallopian tumor involvement is greater than the ovarian involvement with focal carcinoma in situ, which is suggestive of fallopian tube origin.

Clinical History as Provided by Submitting Physician:

y.o. female with 16 cm pelvic mass + omental disease. Suspect ovarian cancer vs primary peritoneal cancer.

A. Right tube + ovary

B. Omentum

Specimens Received:

A: right tube + ovary

B: omentum

Gross Description:

The specimen is received in two containers; each labelled with the patient's name.

Container "A" is labelled "right tube and ovary". The specimen consists of two lesions connected together by a tubular structure. The tubular structure between the two lesions measures 2.0 cm in length and 0.8 cm in diameter. The two lesions measure 3.0 x 2.5 x 1.5 cm and 3.5 x 1.5 x 1.8 cm, respectively. The outer surface of both lesions is irregular and nodular. One of these lesions contains a 2.0 x 1.0 cm ovarian-like tissue (the smallest lesion). Representative sections are submitted as follows:

"A1"&"A2" -the ovary with the lesion

"A3"- "A5" -from the other lesion

"A6" -representative section from the tubular structure

[page 2 of 2]
Container "B" is labelled "omentum". The specimen consists of fibrofatty tissue, which weighs 272 gm and measures 23.0 x 9.0 x 4.0 cm. Multiple whitish nodular lesions are seen. The largest one measures 10.0 cm in maximum dimension. A sample from this tumor is taken for the Tumor Bank. Representative sections are submitted in six cassettes labelled as B1"-B6".

Copies to:

Source: NCI Genomic Data Commons file 7c797492-0f02-4b22-bf04-451abcdea86d (TCGA-36-1578.6BD44F43-7D75-4DF3-891D-7E08291F020C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).